Somatic mutation profile of tumor specimen TCGA-CK-4952-01A (aliquot TCGA-CK-4952-01A-01D-1719-10) from TCGA case TCGA-CK-4952, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 48.8 years (17,826 days).
Specimen TCGA-CK-4952-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cbc24848-2468-4b42-af02-c4f62d2d3cb6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CK-4952-10A (Blood Derived Normal), aliquot TCGA-CK-4952-10A-01D-1719-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93e3ac46-24ad-423b-ae4b-8a1fbefffce9

The open-access MAF lists 163 somatic variants for this specimen: 120 protein-altering or splice-affecting, 42 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 102, Silent 42, Nonsense Mutation 6, Frame Shift Ins 3, Splice Region 3, Frame Shift Del 3, In Frame Del 2, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 22/63 reads (35%) | catalogued as rs137854568, CM910029, COSV57324169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 12/39 reads (31%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDKN1B | c.215dup p.K73Qfs*52 | Frame Shift Ins (INS) | VAF 137/302 reads (45%) | catalogued as rs1555085549; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- GNAS | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 108/233 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs121913495, CM158823, COSV55670349, COSV55671845; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TTN | c.35698A>T p.K11900* (on ENST00000591111; = p.K4476* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as rs869238992, CM1413535, COSV100618025; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABLIM2 | c.1792C>T p.L598F (on ENST00000341937 / NM_001130084.2; = p.L508F on NM_032432.5) | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56402221; called by muse, mutect2, varscan2
- ACOX3 | c.1336C>A p.P446T | Missense Mutation (SNP) | VAF 97/278 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62711464; called by muse, mutect2, varscan2
- ADAMTS5 | c.1102G>T p.E368* | Nonsense Mutation (SNP) | VAF 65/180 reads (36%) | catalogued as COSV53176990, COSV53177451; called by muse, mutect2, varscan2
- ADCY9 | c.2324C>T p.S775F | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.293); catalogued as rs1367661195, COSV53573473; called by muse, mutect2, varscan2
- ADGRB1 | c.2594G>A p.R865H | Missense Mutation (SNP) | VAF 304/393 reads (77%) | SIFT tolerated (0.09); PolyPhen benign (0.322); catalogued as rs781228120, COSV60093990; called by muse, mutect2, varscan2
- ADGRB2 | c.4298G>A p.R1433H | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.608); catalogued as rs368168880; called by muse, mutect2
- ADGRB3 | c.2465G>A p.W822* | Nonsense Mutation (SNP) | VAF 18/33 reads (55%) | catalogued as COSV65390026, COSV65395815; called by muse, mutect2, varscan2
- ADGRF3 | c.2074G>A p.A692T (on ENST00000311519 / NM_001145168.1; = p.A493T on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.053); catalogued as rs1175536790, COSV61049552; called by muse, mutect2, varscan2
- ADGRG7 | c.1046C>T p.S349L | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as COSV56295106; called by muse, mutect2, varscan2
- AKTIP | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.985); catalogued as rs779924211, COSV55815268; called by muse, mutect2, varscan2
- ARMCX2 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 87/204 reads (43%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs369714767, COSV57529630; called by muse, mutect2, varscan2
- AZGP1 | c.336C>T p.N112= | Splice Region (SNP) | VAF 82/230 reads (36%) | catalogued as rs200393898; called by muse, mutect2, varscan2
- BIRC7 | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 95/212 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs761744542, COSV53900744; called by muse, mutect2, varscan2
- CCDC105 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.681); catalogued as rs746595027, COSV52963587; called by muse, mutect2, varscan2
- CENPF | c.5021C>T p.S1674L | Missense Mutation (SNP) | VAF 51/131 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.036); catalogued as COSV100871527, COSV65273728; called by muse, mutect2, varscan2
- CEP63 | c.656C>A p.T219N | Missense Mutation (SNP) | VAF 61/148 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59675214; called by muse, mutect2, varscan2
- CFL1 | c.4-1G>T p.X2_splice | Splice Site (SNP) | VAF 67/166 reads (40%) | catalogued as COSV57379054; called by muse, mutect2, varscan2
- CLSTN2 | c.722A>G p.K241R | Missense Mutation (SNP) | VAF 84/198 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.393); catalogued as COSV71719617; called by muse, mutect2, varscan2
- CNOT6 | c.244T>C p.S82P | Missense Mutation (SNP) | VAF 96/199 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56160707; called by muse, mutect2, varscan2
- CNTN5 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs200717963, COSV54296233, COSV99671964; called by muse, mutect2, varscan2
- COL5A1 | c.2609del p.P870Qfs*204 | Frame Shift Del (DEL) | VAF 56/135 reads (41%) | catalogued as COSV65673103; called by mutect2, pindel, varscan2
- CXCR1 | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 68/148 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as rs149021594; called by muse, mutect2, varscan2
- DENND6B | c.1639C>T p.R547W | Missense Mutation (SNP) | VAF 72/154 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs761717266, COSV63780778; called by muse, mutect2, varscan2
- DGCR6L | c.74T>C p.L25P | Missense Mutation (SNP) | VAF 99/220 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV50618905; called by muse, varscan2
- DIS3L | c.297G>C p.Q99H (on ENST00000319212 / NM_001143688.3; = p.Q16H on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 78/190 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV59911647, COSV59914362; called by muse, mutect2, varscan2
- DYSF | c.3563C>T p.T1188M | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs781339971, COSV50285600; called by muse, mutect2, varscan2
- EHBP1L1 | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 67/145 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751387971, COSV58572130; called by muse, mutect2, varscan2
- ELMO1 | c.374G>C p.G125A | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60300074; called by muse, mutect2, varscan2
- EOLA1 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 286/684 reads (42%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.799); catalogued as rs376113122, COSV63734059; called by muse, varscan2
- FAM193A | c.1963C>A p.H655N | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); catalogued as COSV61192560, COSV61196712; called by muse, mutect2, varscan2
- FAM216A | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 61/224 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs768268801, COSV66600148; called by muse, mutect2, varscan2
- FBXO21 | c.1192C>T p.R398W | Missense Mutation (SNP) | VAF 118/201 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1266197193, COSV57972179; called by muse, mutect2, varscan2
- FBXO42 | c.1082G>A p.R361K | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.34); catalogued as COSV65045232; called by muse, mutect2, varscan2
- GALNT3 | c.1831G>C p.E611Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.027); catalogued as COSV101204964; called by muse, mutect2, varscan2
- GLT8D1 | c.685A>G p.I229V | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.068); catalogued as COSV56476682; called by muse, mutect2, varscan2
- GPR149 | c.1562A>G p.Q521R | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67666609; called by muse, mutect2, varscan2
- GPR149 | c.858A>C p.E286D | Missense Mutation (SNP) | VAF 54/170 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.052); catalogued as COSV67666612; called by muse, mutect2, varscan2
- GREB1 | c.701G>A p.S234N | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.295); catalogued as rs889316662, COSV52183803; called by muse, mutect2, varscan2
- GSTCD | c.1795G>A p.D599N (on ENST00000360505 / NM_001031720.3; = p.D512N on NM_024751.3) | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64732816; called by muse, mutect2, varscan2
- GSTM3 | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 75/193 reads (39%) | catalogued as COSV56661905; called by muse, mutect2, varscan2
- HK3 | c.1646G>A p.R549H | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs150676692; called by muse, mutect2, varscan2
- HTR1A | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 99/264 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60500321; called by muse, mutect2, varscan2
- ILDR1 | c.1387C>T p.R463C (on ENST00000344209 / NM_001199799.2; = p.R419C on NM_175924.4) | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs778163752, CM110963, COSV56549053; called by muse, mutect2, varscan2
- INPPL1 | c.2749C>T p.R917C | Missense Mutation (SNP) | VAF 104/245 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.725); catalogued as rs780472220, COSV53354370; called by muse, mutect2, varscan2
- IQCF1 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 83/175 reads (47%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.947); catalogued as rs769127993, COSV58823254; called by muse, mutect2, varscan2
- KBTBD7 | c.1616C>G p.P539R | Missense Mutation (SNP) | VAF 95/233 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV65266205; called by muse, mutect2, varscan2
- KCNH5 | c.2926C>T p.P976S | Missense Mutation (SNP) | VAF 9/194 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); catalogued as COSV100526927; called by muse, mutect2
- KLF6 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773677946, COSV51494175, COSV99434932; called by muse, mutect2, varscan2
- KLHL34 | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 77/212 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65279024; called by muse, mutect2, varscan2
- KMT2B | c.7715C>T p.T2572M | Missense Mutation (SNP) | VAF 84/187 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as rs867499379, COSV53074231; called by muse, mutect2, varscan2
- KRT36 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 89/214 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.44); catalogued as rs771911925, COSV60202571; called by muse, mutect2, varscan2
- LILRB2 | c.1712G>A p.R571K | Missense Mutation (SNP) | VAF 202/414 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as COSV58743453, COSV58745032; called by muse, mutect2, varscan2
- LRRK2 | c.5020_5023del p.S1674Tfs*5 | Frame Shift Del (DEL) | VAF 42/84 reads (50%) | catalogued as rs749133568; called by mutect2, pindel, varscan2
- LRRN1 | c.770T>C p.L257P | Missense Mutation (SNP) | VAF 64/146 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.377); catalogued as COSV60013191, COSV60016460; called by muse, mutect2, varscan2
- MAGEA6 | c.535G>T p.A179S | Missense Mutation (SNP) | VAF 278/694 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV61448819; called by muse, mutect2, varscan2
- MAP3K15 | c.2984C>T p.P995L | Missense Mutation (SNP) | VAF 122/261 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs140883351, COSV58827652; called by muse, mutect2, varscan2
- MEGF9 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.214); catalogued as COSV64235050; called by muse, mutect2, varscan2
- MST1R | c.3578C>A p.A1193D | Missense Mutation (SNP) | VAF 109/234 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56566620; called by muse, mutect2, varscan2
- MTHFD2L | c.424G>A p.G142S (on ENST00000395759 / NM_001144978.2; = p.G84S on NM_001004346.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1223839197, COSV57466659; called by muse, mutect2, varscan2
- MYH2 | c.4919G>A p.R1640H | Missense Mutation (SNP) | VAF 261/628 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as rs772914345, COSV55434719, COSV55447076; called by muse, mutect2, varscan2
- NFKBIZ | c.713G>T p.S238I | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); catalogued as COSV58199829; called by muse, mutect2, varscan2
- OR10R2 | c.14T>G p.L5R | Missense Mutation (SNP) | VAF 73/146 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); catalogued as COSV63768660; called by muse, mutect2, varscan2
- OR6B2 | c.496G>A p.V166I | Missense Mutation (SNP) | VAF 123/382 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs199866112, COSV53156136; called by muse, mutect2, varscan2
- OXCT2 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 58/164 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756714289, COSV59593491; called by muse, mutect2, varscan2
- PARN | c.618C>T p.T206= | Splice Region (SNP) | VAF 34/77 reads (44%) | catalogued as rs776536192, COSV58364818; called by muse, mutect2, varscan2
- PCDH17 | c.3109A>T p.S1037C | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV64972845, COSV64973045; called by muse, mutect2, varscan2
- PCDHA5 | c.1097C>T p.T366M | Missense Mutation (SNP) | VAF 100/225 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1370566710, COSV65352369; called by muse, mutect2, varscan2
- PCDHB15 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.693); catalogued as COSV50858060; called by muse, mutect2, varscan2
- PDZD4 | c.1481G>A p.R494Q | Missense Mutation (SNP) | VAF 82/168 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.644); catalogued as rs1260319617, COSV51245914; called by muse, mutect2, varscan2
- PHF21B | c.1180C>T p.P394S | Missense Mutation (SNP) | VAF 61/163 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV57557168; called by muse, mutect2, varscan2
- PKD1L2 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 107/293 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.732); catalogued as rs527848230, COSV61413597; called by muse, mutect2, varscan2
- PLXNB3 | c.5114A>C p.K1705T | Missense Mutation (SNP) | VAF 68/169 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62796443; called by muse, mutect2, varscan2
- POLA2 | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 73/179 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs1431737002, COSV55481749; called by muse, mutect2, varscan2
- PRDM10 | c.1893G>A p.V631= | Splice Region (SNP) | VAF 54/139 reads (39%) | catalogued as COSV58800353; called by muse, mutect2, varscan2
- PRDM5 | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 60/161 reads (37%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs759134690, COSV53358105; called by muse, mutect2, varscan2
- PRG3 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 67/141 reads (48%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs779423526, COSV54663411; called by muse, mutect2, varscan2
- PTOV1 | c.728G>A p.G243D | Missense Mutation (SNP) | VAF 68/163 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.286); catalogued as COSV55587182; called by muse, mutect2, varscan2
- RFC4 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs777641769, COSV56216356; called by muse, mutect2, varscan2
- RHEB | c.68C>T p.T23M | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as rs867628277, COSV51262704, COSV51263083; called by muse, mutect2, varscan2
- RIF1 | c.2005G>T p.G669C | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54614905; called by muse, mutect2, varscan2
- RNF165 | c.915A>C p.E305D | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.414); catalogued as rs200332139, COSV53972162, COSV53978216; called by muse, mutect2, varscan2
- RRP12 | c.1937C>T p.T646M | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as rs776080417, COSV59666343; called by muse, mutect2, varscan2
- RRP9 | c.625_627del p.S209del | In Frame Del (DEL) | VAF 63/192 reads (33%) | catalogued as rs1559743679; called by pindel, varscan2
- RYR3 | c.1900C>T p.R634* | Nonsense Mutation (SNP) | VAF 97/234 reads (41%) | catalogued as rs780640652, COSV66783041; called by muse, mutect2, varscan2
- SECTM1 | c.628T>C p.W210R | Missense Mutation (SNP) | VAF 75/176 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.361); catalogued as rs1486008597, COSV53938748; called by muse, mutect2, varscan2
- SLC18A1 | c.1157C>A p.A386D | Missense Mutation (SNP) | VAF 40/55 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52347418; called by muse, mutect2, varscan2
- SLC2A4 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as rs202200041; called by muse, mutect2, varscan2
- SLC6A15 | c.1874T>C p.L625P | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57021588; called by muse, mutect2, varscan2
- SMAD3 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.176); catalogued as COSV59282175; called by muse, varscan2
- STAG3 | c.2597G>A p.R866Q | Missense Mutation (SNP) | VAF 60/150 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs777245782, COSV57928864; called by muse, mutect2, varscan2
- SUPT16H | c.2284G>T p.D762Y | Missense Mutation (SNP) | VAF 91/235 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53523343; called by muse, mutect2, varscan2
- SVIP | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs780103291, COSV62602943; called by muse, mutect2, varscan2
- SYNE1 | c.17629C>A p.P5877T (on ENST00000367255 / NM_182961.4; = p.P5806T on NM_033071.3) | Missense Mutation (SNP) | VAF 93/154 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV54943631; called by muse, mutect2, varscan2
- TCF20 | c.2197A>G p.K733E | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.444); catalogued as COSV59489628; called by muse, mutect2, varscan2
- TENM1 | c.148A>G p.N50D | Missense Mutation (SNP) | VAF 160/388 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV64428566; called by muse, mutect2, varscan2
- TEX15 | c.2717C>A p.T906N (on ENST00000256246; = p.T1289N on NM_001350162.2) | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.877); catalogued as rs1177496721, COSV56344053, COSV56348061; called by muse, mutect2, varscan2
- THEG | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs200771913; called by muse, mutect2, varscan2
- TIMD4 | c.12A>C p.E4D | Missense Mutation (SNP) | VAF 91/220 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.103); catalogued as COSV50854575; called by muse, mutect2, varscan2
- TMED1 | c.641C>T p.T214M | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0.094); catalogued as rs555516048, COSV53033432; called by muse, mutect2, varscan2
- TMEM131 | c.3029A>G p.E1010G | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.922); catalogued as COSV51772898; called by muse, mutect2, varscan2
- TMEM131 | c.3028G>A p.E1010K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.836); catalogued as COSV51772912, COSV51780354; called by muse, mutect2, varscan2
- TNRC6A | c.5392C>T p.R1798C | Missense Mutation (SNP) | VAF 10/173 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100170157; called by muse, mutect2
- TNS4 | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 72/162 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs147274319; called by muse, mutect2, varscan2
- TRIM39 | c.1370G>A p.R457Q | Missense Mutation (SNP) | VAF 69/256 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.98); catalogued as rs748738217, COSV64955110; called by muse, mutect2, varscan2
- TRIOBP | c.6356delinsGT p.E2119Gfs*32 (on ENST00000644935 / NM_001039141.3; = p.E406Gfs*32 on NM_007032.5) | Frame Shift Ins (INS) | VAF 52/192 reads (27%) | catalogued as COSV60375534; called by pindel, varscan2*
- TSHZ2 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.992); catalogued as rs200317435, COSV61587609, COSV61587822; called by muse, mutect2, varscan2
- TUT4 | c.3521G>A p.R1174H | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.114); catalogued as rs549447166, COSV57111951, COSV57117437; called by muse, mutect2, varscan2
- UNC13C | c.11A>C p.N4T | Missense Mutation (SNP) | VAF 102/249 reads (41%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as COSV52856823; called by muse, mutect2, varscan2
- ZDHHC11 | c.68T>C p.V23A | Missense Mutation (SNP) | VAF 86/207 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV52065349; called by muse, mutect2, varscan2
- ZNF471 | c.1672C>A p.L558I | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57290594; called by muse, mutect2, varscan2
- ZNF804A | c.3493G>T p.A1165S | Missense Mutation (SNP) | VAF 107/238 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.137); catalogued as COSV56442045; called by muse, mutect2, varscan2
- CRISPLD1 | c.713del p.N238Ifs*22 | Frame Shift Del (DEL) | VAF 37/139 reads (27%) | called by mutect2, pindel, varscan2
- NLRC5 | c.1801_1803del p.K601del | In Frame Del (DEL) | VAF 74/198 reads (37%) | called by pindel, varscan2
- SPANXB1 | c.40G>T p.V14F | Missense Mutation (SNP) | VAF 263/3350 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.736); called by muse, mutect2
- ADAMTS5 | c.2094C>T p.C698= | Silent (SNP) | VAF 48/125 reads (38%) | catalogued as rs372646537, COSV53179437; called by muse, mutect2, varscan2
- ADGRG4 | c.4893A>G p.T1631= | Silent (SNP) | VAF 56/184 reads (30%) | catalogued as rs939625082, COSV99795833; called by muse, mutect2, varscan2
- ADORA1 | c.156G>A p.A52= | Silent (SNP) | VAF 170/382 reads (45%) | catalogued as COSV58809605; called by muse, mutect2, varscan2
- ADRA1A | c.942C>A p.L314= | Silent (SNP) | VAF 36/309 reads (12%) | catalogued as COSV52360264, COSV52374966; called by muse, mutect2, varscan2
- ALDH5A1 | c.1443G>A p.V481= | Silent (SNP) | VAF 614/684 reads (90%) | catalogued as COSV62373149; called by muse, mutect2, varscan2
- ALPK2 | c.1842C>T p.T614= | Silent (SNP) | VAF 152/349 reads (44%) | catalogued as COSV64491659; called by muse, mutect2, varscan2
- APAF1 | c.987A>G p.A329= (on ENST00000551964 / NM_181861.2; = p.A318= on NM_001160.3) | Silent (SNP) | VAF 28/39 reads (72%) | catalogued as COSV59662792; called by muse, mutect2, varscan2
- BCDIN3D | c.30G>A p.G10= | Silent (SNP) | VAF 60/232 reads (26%) | catalogued as COSV61702328; called by muse, mutect2, varscan2
- C5 | c.2403C>T p.G801= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs200638263, COSV99798135; called by muse, mutect2, varscan2
- CCNB3 | c.2613G>A p.E871= | Silent (SNP) | VAF 60/310 reads (19%) | catalogued as rs782488029, COSV52071641; called by muse, mutect2, varscan2
- CETP | c.306C>T p.S102= | Silent (SNP) | VAF 135/326 reads (41%) | catalogued as COSV52361957; called by muse, mutect2, varscan2
- CPSF1 | c.1137C>T p.P379= | Silent (SNP) | VAF 54/376 reads (14%) | catalogued as rs370731405; called by muse, mutect2
- DCAF11 | c.33C>T p.S11= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV58108681; called by muse, mutect2
- DPP9 | c.135G>A p.S45= (on ENST00000598800; = p.S74= on NM_139159.5) | Silent (SNP) | VAF 79/191 reads (41%) | catalogued as rs747351796, COSV53590296; called by muse, mutect2, varscan2
- DRC7 | c.663G>A p.T221= | Silent (SNP) | VAF 79/191 reads (41%) | catalogued as rs764853726, COSV61053903; called by muse, mutect2, varscan2
- ERLIN1 | c.315C>T p.I105= | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as rs373926474; called by muse, mutect2, varscan2
- GPR12 | c.951C>T p.C317= | Silent (SNP) | VAF 88/236 reads (37%) | catalogued as rs1350867506, COSV67344176; called by muse, mutect2, varscan2
- HDAC9 | c.3138T>C p.D1046= (on ENST00000441542 / NM_178425.3; = p.D1043= on NM_178423.3) | Silent (SNP) | VAF 114/248 reads (46%) | catalogued as COSV67770382; called by muse, mutect2, varscan2
- ITGA2B | c.984C>T p.D328= | Silent (SNP) | VAF 39/82 reads (48%) | catalogued as rs776716953, COSV52231961; called by muse, mutect2, varscan2
- KEL | c.156C>T p.I52= | Silent (SNP) | VAF 126/372 reads (34%) | catalogued as COSV62333589; called by muse, mutect2, varscan2
- LZTS1 | c.1650C>T p.Y550= | Silent (SNP) | VAF 142/192 reads (74%) | catalogued as rs778252648, COSV56116337; called by muse, mutect2, varscan2
- NFIL3 | c.471C>T p.S157= | Silent (SNP) | VAF 96/229 reads (42%) | catalogued as rs1252435849, COSV52683408; called by muse, mutect2, varscan2
- PCDH10 | c.571C>A p.R191= | Silent (SNP) | VAF 46/106 reads (43%) | catalogued as COSV52088148, COSV52090615; called by muse, mutect2, varscan2
- PCDH18 | c.2910C>T p.D970= | Silent (SNP) | VAF 80/197 reads (41%) | catalogued as rs1463998436, COSV61267304; called by muse, mutect2, varscan2
- PENK | c.636C>A p.G212= | Silent (SNP) | VAF 143/258 reads (55%) | catalogued as COSV59240131; called by muse, mutect2, varscan2
- PKN1 | c.1503G>A p.A501= | Silent (SNP) | VAF 39/94 reads (41%) | catalogued as rs149310057; called by muse, mutect2, varscan2
- PLXNB3 | c.5484G>A p.A1828= | Silent (SNP) | VAF 94/218 reads (43%) | catalogued as rs201705898, COSV62796454; called by muse, mutect2, varscan2
- PXDC1 | c.618C>T p.D206= | Silent (SNP) | VAF 158/178 reads (89%) | catalogued as rs759160711, COSV66661354; called by muse, mutect2, varscan2
- SH3TC1 | c.9C>T p.N3= | Silent (SNP) | VAF 53/131 reads (40%) | catalogued as COSV55282894; called by muse, mutect2, varscan2
- SLC36A1 | c.516G>A p.A172= | Silent (SNP) | VAF 101/233 reads (43%) | catalogued as rs751904883, COSV54653083; called by muse, mutect2, varscan2
- SLC4A2 | c.2712G>A p.S904= | Silent (SNP) | VAF 45/106 reads (42%) | catalogued as rs763102759, COSV52539591; called by muse, mutect2, varscan2
- SPSB3 | c.684C>T p.H228= | Silent (SNP) | VAF 57/179 reads (32%) | catalogued as rs778523436, COSV51599621; called by muse, mutect2, varscan2
- SUSD4 | c.180C>T p.P60= | Silent (SNP) | VAF 81/207 reads (39%) | catalogued as rs751927925, COSV59551331; called by muse, mutect2, varscan2
- TGM7 | c.915C>T p.S305= | Silent (SNP) | VAF 75/195 reads (38%) | catalogued as rs376372375; called by muse, mutect2, varscan2
- TMEM120B | c.610C>T p.L204= | Silent (SNP) | VAF 104/159 reads (65%) | catalogued as rs773442629, COSV61182959; called by muse, mutect2, varscan2
- TRPC7 | c.1959C>T p.Y653= | Silent (SNP) | VAF 140/296 reads (47%) | catalogued as rs775960274, COSV61455704; called by muse, mutect2, varscan2
- WDR18 | c.417G>A p.G139= | Silent (SNP) | VAF 39/125 reads (31%) | catalogued as COSV52121375; called by muse, mutect2, varscan2
- WDR86 | c.579G>A p.T193= | Silent (SNP) | VAF 36/65 reads (55%) | catalogued as rs1265023180, COSV57839141; called by muse, mutect2, varscan2
- WSCD2 | c.1599G>A p.A533= | Silent (SNP) | VAF 38/135 reads (28%) | catalogued as rs367689597, COSV54589196; called by muse, mutect2, varscan2
- ZER1 | c.387C>T p.H129= | Silent (SNP) | VAF 47/116 reads (41%) | catalogued as COSV52564953; called by muse, mutect2, varscan2
- ZFPM2 | c.10C>A p.R4= | Silent (SNP) | VAF 309/460 reads (67%) | catalogued as COSV68278055, COSV68292263; called by muse, mutect2, varscan2
- ZNF689 | c.315G>A p.Q105= | Silent (SNP) | VAF 151/371 reads (41%) | catalogued as COSV54908125; called by muse, mutect2, varscan2
- ATP6V0E2 | c.*136C>T | 3'UTR (SNP) | VAF 53/122 reads (43%) | catalogued as rs764371935, COSV70416448; called by muse, mutect2, varscan2
